Somatic mutation profile of tumor specimen TCGA-VS-A9UJ-01A (aliquot TCGA-VS-A9UJ-01A-11D-A42O-09) from TCGA case TCGA-VS-A9UJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 55.5 years (20,264 days).
Specimen TCGA-VS-A9UJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65f2c8fa-35a1-47fd-8d1e-50ca3368da0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9UJ-10A (Blood Derived Normal), aliquot TCGA-VS-A9UJ-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a7c3e45-6e2a-43f7-b0c1-b74a772993c2

The open-access MAF lists 408 somatic variants for this specimen: 323 protein-altering or splice-affecting, 80 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 195, Silent 80, Frame Shift Del 73, Frame Shift Ins 24, Nonsense Mutation 14, Splice Site 10, Splice Region 5, Intron 2, In Frame Del 2, 5'Flank 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.4537dup p.Q1513Pfs*42 | Frame Shift Ins (INS) | VAF 12/26 reads (46%) | catalogued as rs281865377; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AHI1 | c.910dup p.T304Nfs*6 | Frame Shift Ins (INS) | VAF 10/30 reads (33%) | catalogued as rs753874898; ClinVar: pathogenic; called by mutect2, varscan2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 26/128 reads (20%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CCND1 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57119846, COSV57120106, COSV57120715; called by muse, mutect2
- CTCF | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | hotspot (GDC flag); catalogued as rs769948988, COSV50461776; called by muse, mutect2, varscan2
- FLCN | c.1285dup p.H429Pfs*27 | Frame Shift Ins (INS) | VAF 11/20 reads (55%) | catalogued as rs80338682; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 29/61 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.344G>C p.R115P | Missense Mutation (SNP) | VAF 9/28 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.312); catalogued as CM1312620, COSV55890007, COSV55898949, COSV55991501; called by muse, mutect2
- PTEN | c.331T>C p.W111R | Missense Mutation (SNP) | VAF 24/62 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs398123321, CM014084, COSV100911417, COSV64288542, COSV64290246; ClinVar: likely pathogenic; called by muse, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 38/102 reads (37%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ZEB1 | c.1576dup p.V526Gfs*3 | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | catalogued as rs766305306; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA12 | c.7553T>C p.L2518P (on ENST00000272895 / NM_173076.3; = p.L2200P on NM_015657.3) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.733); catalogued as COSV99789304; called by muse, mutect2, varscan2
- AC126283.2 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs777190530, CM1311004, COSV101144288; called by muse, mutect2, varscan2
- ACAD10 | c.850+1G>T p.X284_splice | Splice Site (SNP) | VAF 20/45 reads (44%) | catalogued as COSV100564047; called by muse, mutect2, varscan2
- ADAR | c.3287G>A p.R1096Q | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.994); catalogued as rs747462052, COSV99425769; called by muse, mutect2, varscan2
- ADARB2 | c.1802A>G p.H601R | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV101184548; called by muse, mutect2, varscan2
- AEBP2 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.899); catalogued as rs1485556682, COSV99857666; called by muse, mutect2, varscan2
- AGAP3 | c.1388G>A p.G463D (on ENST00000622464; = p.G499D on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV101257079; called by muse, mutect2
- AHNAK | c.12341G>A p.G4114D | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99946659; called by muse, mutect2, varscan2
- AKAP1 | c.2502C>T p.D834= | Splice Region (SNP) | VAF 6/28 reads (21%) | catalogued as rs781030382, COSV100532778, COSV61806046; called by muse, mutect2, varscan2
- ANAPC7 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV71443800; called by muse, mutect2, varscan2
- ANK3 | c.5740C>T p.R1914W | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1274185754, COSV99778439; called by muse, mutect2, varscan2
- ARHGAP36 | c.613A>G p.T205A | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99357494; called by muse, mutect2, varscan2
- ARHGEF9 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.306); catalogued as rs782418528, COSV99491609; called by muse, mutect2, varscan2
- ARID5B | c.3370C>T p.L1124F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as rs764926817, COSV99689436; called by muse, mutect2, varscan2
- ASCC3 | c.2698G>C p.A900P | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100225511; called by muse, mutect2, varscan2
- ASIC3 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs370369500; called by muse, mutect2
- ATP10A | c.1946G>A p.G649D | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.102); catalogued as COSV100791058; called by muse, mutect2, varscan2
- ATP13A5 | c.2093A>C p.K698T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100664958; called by muse, mutect2, varscan2
- BEND3 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.078); catalogued as COSV100944578; called by muse, mutect2, varscan2
- BRD2 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV100875619; called by muse, mutect2, varscan2
- BRINP1 | c.1426A>G p.S476G | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (1); PolyPhen possibly damaging (0.899); catalogued as COSV99775014; called by muse, mutect2, varscan2
- C12orf42 | c.1009del p.R337Afs*19 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | catalogued as rs771322722; called by mutect2, pindel, varscan2
- C1orf127 | c.2362T>G p.S788A | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV100983461; called by muse, mutect2, varscan2
- C2orf66 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as COSV61098604; called by muse, mutect2, varscan2
- C4orf45 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101465089; called by muse, mutect2, varscan2
- CALCR | c.895G>A p.V299M (on ENST00000649521 / NM_001164737.2; = p.V283M on NM_001742.4) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.288); catalogued as rs151185621; called by mutect2, varscan2
- CALHM1 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as rs371478976; called by muse, varscan2
- CAMSAP1 | c.3290G>A p.R1097Q | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs777664205, COSV100409742; called by muse, mutect2, varscan2
- CAMSAP3 | c.1006del p.R336Gfs*42 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as rs754747174; called by mutect2, pindel, varscan2
- CAPN5 | c.978G>T p.W326C (on ENST00000456580; = p.W286C on NM_004055.5) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99581981; called by muse, mutect2, varscan2
- CARD14 | c.2662C>T p.R888C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.818); catalogued as rs201390554, COSV100413389; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 30/76 reads (39%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 20/44 reads (45%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC27 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99622306; called by muse, mutect2, varscan2
- CCDC34 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1273782378, COSV58725275; called by muse, mutect2, varscan2
- CCDC68 | c.599del p.K200Rfs*7 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | catalogued as rs1439115898; called by mutect2, pindel
- CCNB3 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs372451442, COSV52069879, COSV52074441; called by muse, mutect2
- CDH13 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV99224464; called by muse, mutect2, varscan2
- CDH17 | c.784-1G>T p.X262_splice | Splice Site (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99217222; called by muse, mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 25/70 reads (36%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CFAP299 | c.448del p.R150Dfs*9 | Frame Shift Del (DEL) | VAF 24/44 reads (55%) | catalogued as rs761800837; called by mutect2, varscan2
- CFAP57 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as rs1275194686, COSV100993893; called by muse, mutect2, varscan2
- CHCHD3 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 26/95 reads (27%) | catalogued as COSV99365939; called by muse, mutect2, varscan2
- CHST1 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as rs746564532, COSV100346147; called by muse, mutect2, varscan2
- CHST10 | c.559A>G p.I187V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as COSV99958831; called by muse, mutect2
- CLCA1 | c.1189A>G p.R397G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99322144; called by muse, mutect2, varscan2
- CLRN3 | c.551T>C p.I184T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs765785905, COSV100899746; called by muse, mutect2, varscan2
- CNOT1 | c.3362C>T p.T1121M | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs1277326354, COSV55313058; called by muse, mutect2, varscan2
- CNTN3 | c.2657G>A p.G886D | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99723969; called by muse, mutect2, varscan2
- CNTNAP4 | c.2654T>C p.M885T | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1398916314, COSV100270452; called by muse, mutect2, varscan2
- COL10A1 | c.1636del p.V546* | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs1404987877; called by mutect2, pindel, varscan2
- COL16A1 | c.3310A>G p.K1104E | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99594016; called by muse, mutect2, varscan2
- COL18A1 | c.4472G>A p.R1491Q (on ENST00000359759 / NM_130444.3; = p.R1256Q on NM_030582.4) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs779505082, COSV100645143; called by muse, mutect2, varscan2
- CRTAM | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.592); catalogued as COSV99911916; called by muse, mutect2, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs762650691; called by mutect2, pindel, varscan2
- CSMD1 | c.7889del p.P2630Qfs*9 (on ENST00000520002; = p.P2629Qfs*9 on NM_033225.6) | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | catalogued as COSV59386908; called by mutect2, pindel, varscan2
- CSMD1 | c.5176G>A p.G1726S (on ENST00000520002; = p.G1725S on NM_033225.6) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59358266; called by muse, mutect2, varscan2
- CSNK1D | c.1085G>A p.G362D | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.192); catalogued as COSV99484461; called by muse, mutect2, varscan2
- CUX1 | c.1942C>T p.R648* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as COSV52890936, COSV99470307; called by muse, mutect2, varscan2
- DAGLA | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1350687760, COSV99944210; called by muse, mutect2, varscan2
- DAGLA | c.1758del p.S587Afs*3 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | catalogued as COSV99944376; called by mutect2, pindel, varscan2
- DCBLD1 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.058); catalogued as COSV99757438; called by muse, mutect2
- DCDC1 | c.1054+1G>A p.X352_splice | Splice Site (SNP) | VAF 67/230 reads (29%) | catalogued as COSV100663081; called by muse, mutect2, varscan2
- DCP1B | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV99767399; called by muse, mutect2, varscan2
- DCTN6 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs758874465, COSV99644942; called by muse, mutect2, varscan2
- DGKG | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.265); catalogued as COSV99402993; called by muse, mutect2, varscan2
- DHRS12 | c.844G>T p.D282Y (on ENST00000444610 / NM_001377930.1; = p.G233C on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99523775; called by muse, mutect2, varscan2
- DHX36 | c.2324G>A p.R775K | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as rs1477564808, COSV100273493; called by muse, mutect2, varscan2
- DMBX1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100760721; called by muse, mutect2, varscan2
- DNAH2 | c.6265G>A p.G2089S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.75); catalogued as rs1160862065, COSV66723402; called by muse, mutect2, varscan2
- DNAH7 | c.11911C>T p.P3971S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.81); PolyPhen benign (0.173); catalogued as COSV100414591; called by muse, mutect2, varscan2
- DOCK6 | c.100del p.H34Tfs*14 | Frame Shift Del (DEL) | VAF 17/75 reads (23%) | catalogued as rs766786731; called by mutect2, pindel, varscan2
- DOP1B | c.2995G>A p.V999M | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.117); catalogued as rs549800328, COSV101215217; called by muse, mutect2, varscan2
- DPM1 | c.298A>T p.T100S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.598); catalogued as COSV100857710; called by muse, mutect2, varscan2
- E2F2 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs374901202; called by muse, mutect2, varscan2
- EFCAB12 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs1393220037, COSV100394539; called by muse, mutect2, varscan2
- EGF | c.2175G>A p.M725I | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV99490708; called by muse, mutect2, varscan2
- ENGASE | c.417-2A>G p.X139_splice | Splice Site (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100285728; called by mutect2, varscan2
- EXD3 | c.929A>G p.H310R | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV100573618; called by muse, mutect2
- EXOC3L2 | c.1787G>A p.G596D | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.088); catalogued as COSV99374494; called by muse, mutect2, varscan2
- F8 | c.1016T>C p.M339T | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM012938, COSV100811411; called by muse, mutect2, varscan2
- FAM117A | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs1187569602, COSV99544598; called by muse, mutect2, varscan2
- FAM13A | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs753700549, COSV51996790; called by muse, mutect2, varscan2
- FAM13A | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs766742197, COSV51998799; called by muse, mutect2, varscan2
- FAN1 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV100755915; called by muse, mutect2, varscan2
- FBP1 | c.323C>A p.P108Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV100941122; called by muse, mutect2, varscan2
- FEM1C | c.778del p.R260Efs*7 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | catalogued as rs1561556190; called by mutect2, pindel, varscan2
- FICD | c.390G>A p.M130I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99933996; called by muse, mutect2, varscan2
- FSCN3 | c.1367G>A p.C456Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.374); catalogued as COSV99756735, COSV99757011; called by muse, mutect2, varscan2
- FUBP3 | c.742A>G p.N248D | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100156027; called by muse, mutect2, varscan2
- FURIN | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as rs757314750, COSV99184646; called by muse, mutect2, varscan2
- GALNT6 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV100695374; called by muse, mutect2, varscan2
- GCM1 | c.221A>G p.K74R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99452260; called by muse, mutect2, varscan2
- GFRAL | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs527946821, COSV61229141, COSV61236470; called by muse, mutect2, varscan2
- GIPC3 | c.281dup p.Q95Sfs*23 | Frame Shift Ins (INS) | VAF 22/72 reads (31%) | catalogued as rs750147424; called by mutect2, pindel, varscan2
- GLRX3 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV100487895; called by muse, mutect2, varscan2
- GPAA1 | c.618C>T p.G206= | Splice Region (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100284019; called by muse, mutect2, varscan2
- GPR149 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.092); catalogued as rs749611848, COSV101078301; called by muse, mutect2, varscan2
- GRB7 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs745576131, COSV100485435; called by mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 48/76 reads (63%) | catalogued as rs754199513; called by mutect2, varscan2
- H1-5 | c.615_629del p.P213_K217del | In Frame Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs758100284; called by mutect2, varscan2
- HADHB | c.1013+2T>G p.X338_splice | Splice Site (SNP) | VAF 18/43 reads (42%) | catalogued as COSV100501948; called by muse, mutect2, varscan2
- HMCN1 | c.11849-1G>T p.X3950_splice | Splice Site (SNP) | VAF 20/49 reads (41%) | catalogued as rs1353036822, COSV54887274, COSV99627113; called by muse, mutect2, varscan2
- HMGCS2 | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.436); catalogued as COSV101024749, COSV65569512; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.7-3del | Splice Region (DEL) | VAF 18/64 reads (28%) | catalogued as rs759915055; called by pindel, varscan2
- HNRNPK | c.256C>A p.R86S | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV100698940, COSV61089457; called by muse, mutect2, varscan2
- HPGDS | c.117G>A p.W39* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as COSV99755591; called by muse, mutect2, varscan2
- HPS3 | c.1024C>G p.L342V | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.227); catalogued as rs1407804657, COSV99937317; called by muse, mutect2, varscan2
- HPSE | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60986690; called by mutect2, varscan2
- HSCB | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as rs867188834, COSV99319683; called by muse, mutect2, varscan2
- HYDIN | c.10441C>T p.R3481W | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs76078590, COSV101154480; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as rs747841314; called by mutect2, varscan2
- IDE | c.110del p.K37Rfs*6 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | catalogued as rs1307048524; called by mutect2, pindel, varscan2
- IDS | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.091); catalogued as COSV100557911; called by muse, mutect2, varscan2
- IL6ST | c.1587del p.V530* | Frame Shift Del (DEL) | VAF 63/107 reads (59%) | catalogued as rs776023104; called by mutect2, pindel, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- IPO9 | c.2111C>G p.T704R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV100843379; called by muse, mutect2, varscan2
- ITPR1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs951742390, COSV100230587, COSV57006204; called by muse, mutect2, varscan2
- JPH2 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as COSV100881682; called by muse, mutect2, varscan2
- KCNA3 | c.1340A>G p.Y447C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63901702; called by muse, mutect2, varscan2
- KCNV2 | c.926G>A p.C309Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs200556800, COSV101172554; called by muse, mutect2, varscan2
- KCTD18 | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100728856; called by muse, mutect2, varscan2
- KIF4A | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100979471; called by muse, mutect2, varscan2
- KLHL11 | c.1483A>G p.K495E | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV100044260; called by muse, mutect2, varscan2
- KLHL4 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 24/69 reads (35%) | catalogued as COSV100909374; called by muse, mutect2, varscan2
- KMT2B | c.7715C>T p.T2572M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs867499379, COSV53074231; called by muse, mutect2, varscan2
- KRBOX4 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV99994226; called by muse, mutect2, varscan2
- KRT7 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as rs148429275; called by muse, mutect2, varscan2
- KRTAP10-11 | c.184T>C p.C62R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100552691; called by muse, mutect2, varscan2
- LGI3 | c.536A>G p.K179R | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs1452016400, COSV100102967; called by muse, mutect2, varscan2
- LILRB5 | c.820G>T p.G274W | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100300229; called by muse, mutect2, varscan2
- LIN37 | c.564G>A p.M188I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99137417; called by muse, mutect2, varscan2
- LINGO1 | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.115); catalogued as rs912928791, COSV62438468; called by muse, mutect2, varscan2
- LMX1A | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV54226475, COSV99671992; called by muse, mutect2, varscan2
- LRIT3 | c.1179del p.T394Hfs*33 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as COSV59984945; called by mutect2, pindel, varscan2
- LRRK2 | c.3698G>A p.S1233N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.276); catalogued as COSV100109733; called by muse, mutect2, varscan2
- LYST | c.7831C>T p.R2611C | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67706494; called by muse, mutect2, varscan2
- MAMDC4 | c.3364C>A p.P1122T (on ENST00000445819; = p.P1043T on NM_206920.3) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.99); catalogued as COSV99807934; called by muse, mutect2, varscan2
- MAN2A2 | c.3250G>A p.G1084S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.024); catalogued as rs887194635, COSV100847810; called by muse, mutect2, varscan2
- MAST2 | c.3609G>T p.K1203N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.756); catalogued as COSV100787982; called by mutect2, varscan2
- MASTL | c.1372dup p.I458Nfs*5 | Frame Shift Ins (INS) | VAF 12/84 reads (14%) | catalogued as rs780698479; called by mutect2, varscan2
- MEFV | c.1643C>T p.T548I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.067); catalogued as COSV99560599; called by muse, varscan2
- MGST3 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as rs200730530, COSV63320989; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MKS1 | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.254); catalogued as rs755916212, COSV100439542; called by muse, mutect2, varscan2
- MTDH | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100292461; called by muse, mutect2, varscan2
- MTHFD1 | c.1292A>G p.Q431R | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53698175; called by muse, mutect2, varscan2
- MYH3 | c.3607G>A p.E1203K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1223550924, COSV56863529; called by mutect2, varscan2
- MYO18A | c.735del p.E246Rfs*50 | Frame Shift Del (DEL) | VAF 8/10 reads (80%) | catalogued as COSV62870706; called by mutect2, varscan2
- NALCN | c.1427A>G p.Y476C | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV99214081; called by muse, mutect2
- NCAPH2 | c.420+2T>C p.X140_splice | Splice Site (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100238076; called by muse, mutect2, varscan2
- NCK2 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.255); catalogued as rs754330998, COSV51893725; called by muse, mutect2, varscan2
- NEBL | c.1131G>T p.E377D | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV101009153; called by muse, mutect2, varscan2
- NEFM | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as rs1000384489, COSV99647134; called by muse, mutect2, varscan2
- NEK10 | c.1702G>A p.V568I | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs370504122; called by muse, mutect2, varscan2
- NEUROD6 | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99773972; called by muse, mutect2, varscan2
- NFATC1 | c.2342C>T p.A781V | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV99501206; called by muse, mutect2
- NFATC4 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV51599043; called by muse, mutect2, varscan2
- NKAPL | c.711del p.K239Rfs*39 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as rs201499135, COSV59197754; called by mutect2, pindel, varscan2
- NOMO2 | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.226); catalogued as rs554396078; called by mutect2, varscan2
- NRBP1 | c.1040T>C p.M347T | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV99274906; called by muse, mutect2, varscan2
- NRP1 | c.2627G>A p.G876E | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55167839; called by muse, mutect2, varscan2
- NSUN7 | c.333C>G p.S111R | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100349039; called by muse, mutect2, varscan2
- NUDT11 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV101047030; called by muse, mutect2
- NXF1 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1179084923, COSV99585922; called by muse, mutect2, varscan2
- OR4C15 | c.880G>T p.G294* (on ENST00000314644; = p.G240* on NM_001001920.2) | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV100115539, COSV58952721; called by muse, mutect2, varscan2
- OR52B2 | c.295T>C p.C99R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101603933; called by muse, varscan2
- OR5T2 | c.949T>C p.Y317H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100506886; called by muse, mutect2, varscan2
- OSM | c.640del p.E214Rfs*15 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs150499755, COSV53160967; called by mutect2, pindel, varscan2
- OTOS | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100108809; called by muse, mutect2, varscan2
- P2RX3 | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV54441980, COSV99628476; called by muse, mutect2, varscan2
- PANX2 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99348128; called by muse, mutect2, varscan2
- PCDHA2 | c.1153G>A p.V385I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV100973760; called by muse, varscan2
- PCDHA9 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV100970248, COSV65329311; called by muse, mutect2, varscan2
- PCDHGA7 | c.2314del p.Q772Sfs*5 | Frame Shift Del (DEL) | VAF 23/73 reads (32%) | catalogued as COSV53950889; called by mutect2, pindel, varscan2
- PCLO | c.11639C>A p.P3880H | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100430187; called by muse, mutect2
- PCYOX1L | c.910del p.L304Cfs*10 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs1421574639; called by mutect2, pindel, varscan2
- PDHA2 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as rs1332347062, COSV99756733; called by muse, mutect2, varscan2
- PDZD8 | c.1040G>A p.C347Y | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100559480; called by muse, mutect2, varscan2
- PEAK1 | c.3905C>T p.A1302V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.494); catalogued as COSV100432767; called by muse, mutect2, varscan2
- PFKP | c.793del p.R265Gfs*2 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs1161592176; called by mutect2, pindel, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PLPP2 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as COSV99514591; called by muse, mutect2, varscan2
- PNRC1 | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV100259850; called by muse, mutect2, varscan2
- POLQ | c.566G>A p.C189Y | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51747139, COSV99951994; called by muse, mutect2, varscan2
- POLR3D | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs374647731; called by muse, mutect2, varscan2
- POU4F3 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV57945418; called by muse, mutect2, varscan2
- PPP2R3C | c.67del p.S23Vfs*5 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | catalogued as rs758484975; called by mutect2, varscan2
- PPP6R2 | c.200del p.L67Rfs*19 | Frame Shift Del (DEL) | VAF 6/13 reads (46%) | catalogued as rs1569386664; called by mutect2, varscan2
- PRB2 | c.584del p.P195Hfs*236 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as rs768275136; called by pindel, varscan2
- PRKG1 | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100908069; called by muse, mutect2, varscan2
- PRPH | c.761A>G p.E254G | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs775233209, COSV57679955; called by muse, mutect2, varscan2
- PSMC2 | c.65T>C p.I22T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.05); catalogued as COSV99485226; called by muse, mutect2, varscan2
- PSMD8 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); catalogued as rs183916438, COSV99286297; called by mutect2, varscan2
- PXYLP1 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745590323, COSV53892507; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 32/74 reads (43%) | catalogued as rs762006287; called by mutect2, varscan2
- RGR | c.325A>G p.S109G | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV100812889; called by muse, mutect2
- RHPN2 | c.909A>T p.E303D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0.409); catalogued as COSV99577330; called by muse, mutect2, varscan2
- RNF138 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs1481305138, COSV99857436; called by muse, mutect2, varscan2
- RPS14 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs1391370949, COSV56316776; called by muse, mutect2, varscan2
- RSPH3 | c.683G>T p.R228M (on ENST00000252655; = p.R86M on NM_031924.8) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99396264; called by muse, mutect2
- RTN1 | c.1613del p.P538Lfs*36 | Frame Shift Del (DEL) | VAF 17/44 reads (39%) | catalogued as COSV99032319; called by mutect2, pindel, varscan2
- RUNX2 | c.1273C>T p.P425S (on ENST00000371438; = p.P403S on NM_001015051.3) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100767260; called by muse, mutect2, varscan2
- SCFD2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.309); catalogued as COSV101189327; called by muse, mutect2, varscan2
- SCN7A | c.4092G>T p.K1364N | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370436682, COSV101313155; called by muse, mutect2, varscan2
- SEC11A | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV51614417; called by muse, mutect2, varscan2
- SERPINE1 | c.85T>C p.S29P | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99776645; called by muse, mutect2, varscan2
- SGSM3 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as rs756348980, COSV99960286; called by muse, mutect2, varscan2
- SLAMF1 | c.829dup p.S277Kfs*19 | Frame Shift Ins (INS) | VAF 37/84 reads (44%) | catalogued as rs751442558; called by mutect2, varscan2
- SLC6A6 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100692052; called by muse, mutect2, varscan2
- SLFN12 | c.555del p.F185Lfs*12 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs747319777; called by mutect2, varscan2
- SLIT3 | c.4318G>A p.G1440S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs148573931; called by muse, mutect2, varscan2
- SLITRK4 | c.323C>A p.A108E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV100567254; called by muse, mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 48/144 reads (33%) | catalogued as rs763364024; called by mutect2, varscan2
- SNIP1 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as rs746110236, COSV56168284; called by muse, mutect2, varscan2
- SPATA2L | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs201257207, COSV57048594; called by muse, mutect2, varscan2
- ST7L | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV100573715; called by muse, mutect2, varscan2
- ST8SIA3 | c.463A>G p.M155V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | PolyPhen benign (0); catalogued as COSV100129419; called by muse, mutect2, varscan2
- SYNE1 | c.2474C>T p.T825M (on ENST00000367255 / NM_182961.4; = p.T832M on NM_033071.3) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs777634676, COSV99558953; called by muse, mutect2, varscan2
- SYNE1 | c.1941del p.R648Efs*13 (on ENST00000367255 / NM_182961.4; = p.R655Efs*13 on NM_033071.3) | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | catalogued as rs775516009; called by mutect2, pindel, varscan2
- SYNGAP1 | c.3955G>C p.A1319P | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV53385462; called by muse, mutect2, varscan2
- TAF1 | c.1913G>T p.G638V (on ENST00000373790 / NM_138923.4; = p.G659V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99335270; called by muse, mutect2, varscan2
- TAF1B | c.834del p.Y278* | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | catalogued as COSV55155775, COSV99721849; called by mutect2, varscan2
- TAGLN2 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100231041; called by muse, mutect2, varscan2
- TBX22 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs917472096, CD040194, COSV64784942; called by muse, mutect2, varscan2
- TCOF1 | c.760G>T p.G254* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100077152; called by muse, mutect2, varscan2
- TFAP2C | c.922G>A p.G308S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99571411; called by muse, mutect2, varscan2
- TFF2 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs765949011, COSV99367130; called by muse, mutect2, varscan2
- TGIF2LX | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as rs1379139812, COSV52213936; called by muse, mutect2, varscan2
- TJP3 | c.717+2T>C p.X239_splice | Splice Site (SNP) | VAF 20/33 reads (61%) | catalogued as COSV99515929; called by muse, mutect2, varscan2
- TNRC18 | c.4627del p.R1543Afs*13 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as rs754233336; called by mutect2, pindel, varscan2
- TNRC6C | c.1844del p.N615Mfs*45 | Frame Shift Del (DEL) | VAF 36/48 reads (75%) | catalogued as rs867658870, COSV56951956; called by mutect2, varscan2
- TRABD2A | c.1298G>A p.R433Q (on ENST00000409520 / NM_001277053.2; = p.R384Q on NM_001080824.3) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.457); catalogued as rs778315280, COSV52879681; called by muse, mutect2, varscan2
- TRH | c.319del p.A107Lfs*23 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | catalogued as rs770451471, COSV57014685; called by mutect2, pindel, varscan2
- TRIM56 | c.1462C>A p.L488I | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.522); catalogued as COSV100047166; called by muse, mutect2, varscan2
- TRMT2B | c.303G>A p.K101= | Splice Region (SNP) | VAF 44/137 reads (32%) | catalogued as rs1164200950, COSV100105285; called by muse, mutect2, varscan2
- TTC21B | c.3357C>G p.H1119Q | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54632333, COSV99692114; called by muse, mutect2, varscan2
- TULP4 | c.4306C>T p.P1436S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV65574577; called by muse, mutect2, varscan2
- UCK2 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.937); catalogued as COSV100902905; called by muse, mutect2, varscan2
- UGCG | c.1094del p.L365Cfs*9 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | catalogued as rs1243652090; called by mutect2, varscan2
- UGT2A3 | c.342del p.F114Lfs*4 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs763425928; called by pindel, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | catalogued as rs767420916; called by mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs764735138; called by mutect2, varscan2
- VEGFB | c.386del p.K129Rfs*5 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | catalogued as rs747177567, COSV100374813; called by mutect2, varscan2
- VPS35L | c.1224+1G>A p.X408_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99220316; called by muse, mutect2
- VWA3A | c.1910G>A p.G637D | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100240771; called by muse, mutect2, varscan2
- WDCP | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99721998; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 18/26 reads (69%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WNK3 | c.3250C>T p.P1084S | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100671117; called by muse, mutect2, varscan2
- XIRP1 | c.2866C>T p.P956S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.612); catalogued as COSV61137016; called by muse, mutect2, varscan2
- ZAN | c.2223del p.T742Qfs*259 | Frame Shift Del (DEL) | VAF 30/83 reads (36%) | catalogued as rs757519687; called by mutect2, varscan2
- ZBTB38 | c.1847T>C p.L616P | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as COSV100375534; called by muse, mutect2, varscan2
- ZC3H12B | c.1960C>T p.Q654* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100161634; called by muse, mutect2, varscan2
- ZFPM1 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1469510709, COSV60322251; called by muse, mutect2, varscan2
- ZNF202 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100278972; called by muse, mutect2, varscan2
- ZNF331 | c.9G>T p.Q3H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV99467123; called by muse, mutect2, varscan2
- ZNF407 | c.6589C>T p.Q2197* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100225381; called by muse, varscan2
- ZNF532 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.989); catalogued as rs1423368251, COSV60171914; called by muse, mutect2, varscan2
- ZNF554 | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs367609998; called by muse, mutect2
- ZNF565 | c.946G>A p.E316K (on ENST00000355114; = p.E276K on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs775971742, COSV58410966; called by muse, mutect2, varscan2
- ZNF710 | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99184114; called by muse, mutect2
- ZNF836 | c.1259G>A p.G420D | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs764010233, COSV100440778; called by muse, mutect2, varscan2
- ALAS2 | c.1275dup p.M426Hfs*66 | Frame Shift Ins (INS) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- ALPK2 | c.2556_2557del p.C853Ffs*3 | Frame Shift Del (DEL) | VAF 7/16 reads (44%) | called by mutect2, varscan2
- ARID1A | c.2401_2402dup p.Q802Vfs*32 | Frame Shift Ins (INS) | VAF 11/50 reads (22%) | called by mutect2, pindel, varscan2
- ARID1B | c.3317del p.N1106Tfs*11 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | called by mutect2, pindel, varscan2
- ATP13A5 | c.1162del p.R388Gfs*3 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- BUB1 | c.3096dup p.H1033Sfs*32 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | called by mutect2, pindel, varscan2
- C14orf39 | c.1188_1189del p.T397* | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | called by pindel, varscan2
- C19orf12 | c.198_199dup p.A67Gfs*7 (on ENST00000392278 / NM_001031726.3; = p.A56Gfs*7 on NM_031448.6) | Frame Shift Ins (INS) | VAF 13/44 reads (30%) | called by mutect2, varscan2
- CASKIN2 | c.835+1del p.X279_splice | Splice Site (DEL) | VAF 7/22 reads (32%) | called by mutect2, pindel, varscan2
- CCDC14 | c.1581dup p.F528Ifs*2 (on ENST00000488653; = p.F480Ifs*2 on NM_022757.5) | Frame Shift Ins (INS) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- CFHR1 | c.53del p.G18Efs*11 | Frame Shift Del (DEL) | VAF 41/213 reads (19%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by pindel, varscan2
- ECT2L | c.620del p.P207Lfs*3 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- EIF4B | c.988del p.Q330Kfs*5 | Frame Shift Del (DEL) | VAF 29/88 reads (33%) | called by mutect2, pindel, varscan2
- EIF4G3 | c.247del p.Q83Nfs*43 | Frame Shift Del (DEL) | VAF 40/109 reads (37%) | called by mutect2, pindel, varscan2
- FAM83E | c.1411dup p.R471Pfs*78 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- GRIK2 | c.2463_2465del p.G822del | In Frame Del (DEL) | VAF 7/32 reads (22%) | called by pindel, varscan2
- HTT | c.7153C>T p.P2385S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, mutect2
- IPO11 | c.2210del p.L737* | Frame Shift Del (DEL) | VAF 36/142 reads (25%) | called by mutect2, pindel, varscan2
- KCNQ3 | c.1032del p.F344Lfs*105 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- KIAA1217 | c.213del p.R73Efs*22 | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | called by mutect2, pindel, varscan2
- KMT2B | c.6452_6456del p.G2151Dfs*6 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- LRRC37A3 | c.20C>A p.P7Q | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MRTFA | c.1031dup p.D345Gfs*72 | Frame Shift Ins (INS) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
- NBEAL1 | c.4809dup p.V1604Sfs*3 | Frame Shift Ins (INS) | VAF 11/30 reads (37%) | called by mutect2, pindel, varscan2
- NHSL2 | c.1923dup p.P642Tfs*44 (on ENST00000510661; = p.P1008Tfs*44 on NM_001013627.2) | Frame Shift Ins (INS) | VAF 32/86 reads (37%) | called by mutect2, varscan2
- NSD1 | c.5508del p.A1837Lfs*12 | Frame Shift Del (DEL) | VAF 23/60 reads (38%) | called by mutect2, pindel, varscan2
- NUB1 | c.1350del p.E451Rfs*13 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | called by mutect2, pindel, varscan2
- OTOL1 | c.718dup p.D240Gfs*2 | Frame Shift Ins (INS) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- PARGP1 | n.1203A>G | Splice Region (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
- PJA1 | c.825dup p.D276* | Frame Shift Ins (INS) | VAF 9/18 reads (50%) | called by mutect2, varscan2
- RAB3GAP2 | c.2227del p.W743Gfs*32 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | called by mutect2, pindel, varscan2
- RPS6KA5 | c.1342del p.S448Vfs*9 | Frame Shift Del (DEL) | VAF 32/118 reads (27%) | called by mutect2, pindel, varscan2
- SCLT1 | c.1269del p.A424Qfs*6 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- SETD5 | c.3855del p.S1286Lfs*84 | Frame Shift Del (DEL) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- SMARCA2 | c.4346dup p.K1450Qfs*9 | Frame Shift Ins (INS) | VAF 22/86 reads (26%) | called by pindel, varscan2
- SMC2 | c.820del p.I274* | Frame Shift Del (DEL) | VAF 38/114 reads (33%) | called by mutect2, pindel, varscan2
- SMO | c.2081del p.P694Lfs*82 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- SQLE | c.955G>T p.A319S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.446); called by muse, mutect2
- TAF3 | c.1054dup p.I352Nfs*3 | Frame Shift Ins (INS) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- TELO2 | c.1203del p.V402Cfs*6 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by pindel, varscan2
- TRERF1 | c.1830del p.S611Pfs*104 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by mutect2, pindel, varscan2
- UNC5C | c.1471del p.Q491Kfs*15 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | called by mutect2, pindel, varscan2
- USP6NL | c.302dup p.P102Tfs*7 | Frame Shift Ins (INS) | VAF 15/49 reads (31%) | called by mutect2, pindel, varscan2
- VWF | c.7651dup p.Q2551Pfs*16 | Frame Shift Ins (INS) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- WDR90 | c.1201del p.E401Sfs*34 | Frame Shift Del (DEL) | VAF 3/20 reads (15%) | called by pindel, varscan2
- XKR4 | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- ZNF329 | c.934del p.E312Kfs*159 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- ABCA4 | c.1821G>T p.G607= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV100933085; called by muse, mutect2, varscan2
- ACAD9 | c.1161C>A p.S387= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs754678565, COSV100459072, COSV58308706; called by muse, mutect2, varscan2
- ACAP3 | c.499C>T p.L167= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs145180258; called by muse, mutect2, varscan2
- ADGRG4 | c.7722G>A p.T2574= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs749683474, COSV54965405; called by muse, mutect2, varscan2
- AGBL5 | c.345C>T p.T115= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100549000; called by muse, mutect2, varscan2
- ARHGAP32 | c.3474T>C p.S1158= (on ENST00000310343 / NM_001378025.1; = p.S809= on NM_014715.4) | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100087416; called by muse, mutect2, varscan2
- ATP10A | c.4122C>T p.D1374= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV100791057; called by muse, mutect2, varscan2
- ATP5PB | c.372T>C p.A124= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV100867629; called by muse, mutect2, varscan2
- BTAF1 | c.4878C>T p.C1626= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs199985153, COSV56431833; called by muse, mutect2, varscan2
- C16orf86 | c.438C>A p.P146= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs780866120, COSV99708155; called by muse, mutect2, varscan2
- C16orf89 | c.729C>T p.Y243= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs370420720; called by muse, varscan2
- C1QC | c.393C>A p.P131= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV101009448; called by muse, mutect2
- CACNA1A | c.438C>T p.F146= | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as rs755662617, COSV64196149, COSV64205831; called by muse, mutect2, varscan2
- CCDC126 | c.210C>T p.V70= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs779145372, COSV56739129; called by muse, mutect2, varscan2
- CCNT2 | c.933G>A p.A311= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs781411502, COSV99750459; called by muse, mutect2, varscan2
- CD37 | c.762A>G p.L254= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100114938; called by muse, mutect2, varscan2
- CDKL5 | c.1470G>A p.G490= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs1290943262, COSV101184203; called by muse, mutect2, varscan2
- CHD9 | c.1254T>C p.F418= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV101272035; called by muse, mutect2, varscan2
- CHRD | c.882G>A p.Q294= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99200313; called by muse, mutect2, varscan2
- CNGB1 | c.1770C>T p.D590= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs770735553, COSV51901289; called by muse, mutect2, varscan2
- COL22A1 | c.4128C>A p.V1376= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100277517; called by muse, mutect2, varscan2
- CSMD2 | c.6256C>T p.L2086= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- CUL2 | c.2199C>T p.R733= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV101039117; called by muse, mutect2, varscan2
- DAXX | c.636C>G p.L212= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV99801850; called by muse, mutect2, varscan2
- DBN1 | c.1446C>T p.N482= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs370979617; called by muse, mutect2, varscan2
- DCPS | c.420G>A p.L140= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs1424647918, COSV99703409; called by muse, mutect2, varscan2
- DGAT2 | c.750C>A p.G250= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV99929651; called by muse, mutect2, varscan2
- DGKQ | c.1455G>A p.T485= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs142252547, COSV99892521; called by muse, mutect2, varscan2
- DLGAP2 | c.789G>A p.A263= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs1308671801, COSV70102535; called by muse, mutect2, varscan2
- DYNC2H1 | c.6351T>C p.D2117= | Silent (SNP) | VAF 56/136 reads (41%) | catalogued as rs1379890053, COSV100518141; called by muse, mutect2, varscan2
- ELP5 | c.468C>A p.S156= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100020962; called by muse, mutect2, varscan2
- EXOC3L1 | c.255G>A p.Q85= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs373143384; called by muse, mutect2, varscan2
- FCRL2 | c.1213C>T p.L405= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV100829872; called by muse, mutect2, varscan2
- FOXP2 | c.825A>G p.G275= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100646471; called by muse, mutect2, varscan2
- GREM2 | c.189C>T p.T63= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs1253433623, COSV100547419; called by muse, mutect2, varscan2
- HFE | c.825G>T p.G275= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100352553; called by muse, mutect2, varscan2
- HRNR | c.888C>T p.H296= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs142350682; called by muse, mutect2, varscan2
- KDM5B | c.2031G>A p.S677= | Silent (SNP) | VAF 20/28 reads (71%) | catalogued as rs773754032, COSV99350365; called by muse, mutect2, varscan2
- KLHL41 | c.366C>T p.C122= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs199941904, COSV52929850; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRTAP4-3 | c.150C>T p.C50= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV101194149; called by muse, mutect2, varscan2
- LENG8 | c.1047T>C p.A349= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs746460519, COSV100457311; called by muse, mutect2, varscan2
- MAP2K3 | c.294C>T p.T98= (on ENST00000342679 / NM_145109.3; = p.T69= on NM_002756.4) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs568850558, COSV100383667; called by muse, mutect2, varscan2
- MAP3K15 | c.2127C>T p.I709= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs745656941, COSV58832963; called by muse, mutect2, varscan2
- MAP3K4 | c.1233C>T p.G411= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV100815207; called by muse, mutect2, varscan2
- MIA3 | c.5541A>G p.S1847= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV100388167; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1020C>T p.D340= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV100825054; called by muse, mutect2, varscan2
- MTAP | c.915T>C p.H305= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs755597494, COSV101289185; called by muse, varscan2
- MYO3A | c.2055T>C p.R685= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV99779114; called by muse, mutect2, varscan2
- NUDT18 | c.783C>G p.G261= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV99248865; called by muse, mutect2, varscan2
- OBSCN | c.8568C>T p.P2856= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs368771823; called by muse, mutect2, varscan2
- OR10H1 | c.480C>A p.T160= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV100612400; called by muse, mutect2, varscan2
- PCDHGA5 | c.1974C>T p.F658= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs373044204; called by muse, mutect2, varscan2
- PDE10A | c.1605C>T p.H535= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100604903; called by muse, mutect2, varscan2
- PFKP | c.156C>T p.Y52= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs769414665, COSV101127123; called by muse, varscan2
- PIGQ | c.159G>A p.R53= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99215930; called by muse, mutect2, varscan2
- PRDM16 | c.132G>A p.S44= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as rs373546344, COSV54600824; called by muse, mutect2, varscan2
- PRPSAP2 | c.576G>A p.S192= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs752954335, COSV99264439; called by muse, mutect2, varscan2
- PRRC2B | c.462C>T p.H154= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100621659; called by muse, mutect2, varscan2
- PSPC1 | c.153G>A p.A51= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100142239; called by muse, mutect2, varscan2
- RAPGEF1 | c.1449G>A p.S483= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs747924663, COSV100940420; called by mutect2, varscan2
- RGS18 | c.378G>A p.K126= | Silent (SNP) | VAF 96/268 reads (36%) | catalogued as COSV100817717; called by muse, mutect2, varscan2
- RMDN1 | c.126C>T p.F42= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99547434; called by muse, mutect2, varscan2
- SALL1 | c.1326C>T p.S442= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs143605364, COSV51762903; called by muse, mutect2, varscan2
- SCARB1 | c.957C>T p.G319= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99909095; called by muse, mutect2, varscan2
- SDC2 | c.108C>A p.S36= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100142752; called by muse, mutect2, varscan2
- SH2D3A | c.711A>G p.R237= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV99837906; called by muse, mutect2, varscan2
- SLC25A16 | c.390T>C p.H130= | Silent (SNP) | VAF 56/166 reads (34%) | catalogued as rs1173070967, COSV99770056; called by muse, mutect2, varscan2
- SMARCC1 | c.1884C>A p.T628= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99592589; called by muse, mutect2, varscan2
- SOBP | c.942G>T p.P314= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV100432985; called by muse, mutect2, varscan2
- SPRY1 | c.481C>T p.L161= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1362171730, COSV100201797; called by muse, mutect2, varscan2
- STX18 | c.939C>T p.R313= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs1172775388, COSV100086105; called by muse, mutect2, varscan2
- TACC2 | c.3930C>T p.S1310= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100552016; called by muse, mutect2, varscan2
- THBS1 | c.222G>A p.K74= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV99527780; called by muse, mutect2, varscan2
- TLR9 | c.2809C>T p.L937= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV62347854; called by muse, mutect2
- TNNI1 | c.210C>T p.H70= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs138552643, COSV60188917; called by muse, varscan2
- TNXB | c.840C>T p.C280= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100926143; called by muse, mutect2, varscan2
- TRPV5 | c.2019T>C p.S673= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs751167967, COSV99520293; called by muse, mutect2, varscan2
- TUBGCP6 | c.2628T>C p.A876= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1041833559, COSV99955233; called by muse, mutect2, varscan2
- ZBTB4 | c.471G>T p.G157= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV100263066; called by muse, mutect2, varscan2
- ZNF467 | c.1062T>G p.P354= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100117877; called by muse, mutect2
- DNAH8 | chr6:38722879 G>A | 5'Flank (SNP) | VAF 10/25 reads (40%) | catalogued as rs748780209, COSV100544194; called by muse, mutect2, varscan2
- HDAC2 | c.-35G>T | 5'UTR (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100892584; called by mutect2, varscan2
- MIR513A1 | n.110C>T | RNA (SNP) | VAF 20/61 reads (33%) | called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1910C>T | Intron (SNP) | VAF 13/34 reads (38%) | catalogued as rs371088689; called by muse, mutect2, varscan2
- ZSCAN32 | c.915-148C>T | Intron (SNP) | VAF 15/48 reads (31%) | catalogued as rs1176727327, COSV100514289; called by muse, mutect2, varscan2
